Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A2NC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A2NC-06A (Metastatic).

FINAL DIAGNOSIS:

PART 1: LEFT CHEST WALL, MASS, RIB, INTERCOSTAL MUSCLE AND PLEURA, FIBROFATTY TISSUE, RESECTION -

- A. METASTATIC MELANOMA MULTIPLE FOCI, LARGEST NODULE 4.5 CM. IN INTERCOSTAL MUSCLE AND ADJACENT FAT.
- B. ANGIOLYMPHATIC INVASION PRESENT.
- C. SOFT TISSUE MARGINS CLOSE BUT FREE.

PART 2: SUPERIOR PERICARDIAL FAT, EXCISION -
FIBROFATTY TISSUE NEGATIVE FOR TUMOR.

Collection Date:

COMMENT:

The tumor is composed of spindle and epithelial cells. The patient had previous biopsies of tumor with similar histology. Immunostains performed then had revealed tumor to be positive for S100, HMB45, keratin A and negative for cytokeratin. Bone is pending decalcification and will be reported as an addendum.

ICD-0-3

Melanoma, NOS 8720/3

Site: Chest wall, NOS C76.1

fw
8/19/11

Source: NCI Genomic Data Commons file da8da20c-9669-4737-8b6a-53aac5512982 (TCGA-ER-A2NC.F0F5FECE-CED1-4907-863F-6B9A60C777D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).